TCGA case TCGA-QR-A70D — Pheochromocytoma and Paraganglioma (TCGA-PCPG)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Paragangliomas and Glomus Tumors; Primary site: Connective, subcutaneous and other soft tissues; Tissue source site: National Institutes of Health. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/9cb0dea2-8c02-48c1-8217-0529cc57addc

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 39 years; Vital status: Alive.

Diagnoses (4)
1. Aortic body tumor (the primary disease): ICD-O-3 morphology code: 8691/1; ICD-10 code: C49.3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of thorax; Site of resection or biopsy: Connective, subcutaneous and other soft tissues of thorax; Classification of tumor: primary; Age at diagnosis: 39.5 years (14,412 days); Year of diagnosis: 2012; Prior malignancy: yes; Synchronous malignancy: Yes; Prior treatment: No; Days to last follow up: 7 days.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 10.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Paraganglioma, NOS: ICD-O-3 morphology code: 8680/1; Tissue or organ of origin: Head, face or neck, NOS; Laterality: Left; Classification of tumor: Prior primary; Age at diagnosis: 34.8 years (12,723 days); Days to diagnosis: -1,689 days (-4.6 years).
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: -1,507 days (-4.1 years).
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
3. Paraganglioma, NOS: ICD-O-3 morphology code: 8680/1; Tissue or organ of origin: Heart; Classification of tumor: Synchronous primary; Age at diagnosis: 35.4 years (12,936 days); Days to diagnosis: -1,476 days (-4.0 years).
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: -442 days (-1.2 years).
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
4. Paraganglioma, NOS: ICD-O-3 morphology code: 8680/1; Tissue or organ of origin: Pelvis, NOS; Laterality: Right; Classification of tumor: Synchronous primary; Age at diagnosis: 35.4 years (12,936 days); Days to diagnosis: -1,476 days (-4.0 years).
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 0 days.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Follow-up (2 entries)
- Day 0 (prior to diagnosis): History of tumor: Yes; History of tumor type: Phenochromocytoma or Paraganglioma.
- Days to follow up: 7 days; Disease response: Tumor Free.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-QR-A70D-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 20 mg.
  Slide TCGA-QR-A70D-01A-01-TS1: Section location: Top; Percent tumor cells: 65; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 35; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-QR-A70D-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-QR-A70D-10B: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History pheo or para include benign: Yes; History pheo or para anatomic site: L Glomus Jugulare PGl,  Cardiac PGL; History neoadjuvant treatment: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Primary pathology: Submitted tumor site: Extra-adrenal Site; Site of primary tumor other: Aorto-caval peripancreatic PGL, presacral PGL; Histologic diagnosis: Paraganglioma; Ct scan preop results: Yes; Lymph nodes examined: Yes.
- Other malignancy form 1: Malignancy type: Synchronous Malignancy; Other malignancy anatomic site: Heart; Other malignancy histological type: paraganglioma.
- Other malignancy form 1, Surgery: Other malignancy surgery type: resection of paraganglioma.
- Other malignancy form 2: Malignancy type: Synchronous Malignancy; Other malignancy anatomic site: Pelvis; Other malignancy histological type: paraganglioma.
- Other malignancy form 2, Surgery: Other malignancy surgery type: resection of paragangliomas.
- Other malignancy form 3: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Head/Neck; Other malignancy histological type: paraganglioma.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 7 days; disease-specific survival: no event (censored), 7 days; disease-free interval: no event (censored), 7 days; progression-free interval: no event (censored), 7 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-QR-A70D-01A-11D-A35C-01): tumor purity 0.75, ploidy 1.92, whole-genome doublings 0.
